Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91A, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91A-01A (Primary Tumor).

Collect date:

Adenocarcinoma mucinous
NOS 8480/3
Site: Body & stomach C16.2
JAS 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "Mesocolon implant"

Mucoproducing adenocarcinoma, poorly differentiated, with "signet ring" cells.

2 - "Epiplon"

Absence of neoplasia.

3 - "Stomach (according to standardization)"

Poorly differentiated mucinous adenocarcinoma (measuring 14 cm), infiltrating up to perigastric adipose tissue.

Foci of vascular and perineural invasions present.

Metastasis in two lymph nodes from chain 3, one from chain 4d, one from chain 6, two from chain 7, three from chain 8a and two from chain 8p (total: 11/29).

Fragment of pancreatic tissue without changes.

Proximal margin uninvolved by neoplasia.

Distal margin uninvolved by neoplasia, however exiguous (1.0 mm).

4 - "Esophageal margin"

Ectopic gastric mucosa in distal esophagus.

Absence of neoplasia.

5 - "Gallbladder"

Chronic cholecystitis with cholesterosis.

Criteria	mw 4/15/13	Yes	No
SPAA Discrepancy			☒
Prevalence History			☒
Qual/Quantitative Primary Site			☒

Source: NCI Genomic Data Commons file a4437eee-cd7c-4161-837f-1412b34f17ae (TCGA-VQ-A91A.C3F4F5E9-3407-4ADF-AEED-EB25A79EF375.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).